Somatic mutation profile of tumor specimen MP2PRT-PAVKIZ-TMP1-A (aliquot MP2PRT-PAVKIZ-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVKIZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (804 days).
Specimen MP2PRT-PAVKIZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8013ec1-dc7b-4953-a5dc-23ecbe13eeea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVKIZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVKIZ-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e275cc90-cf5e-48ef-8fdd-e5f37cc2b80e

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2049A>T p.R683S | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519723, COSV67569539, COSV67577012; ClinVar: pathogenic; called by muse, mutect2, varscan2
- JAK2 | c.2624C>A p.T875N | Missense Mutation (SNP) | VAF 10/320 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1057520016, COSV67598981; ClinVar: likely pathogenic; called by muse, mutect2
- CES5A | c.1603C>T p.R535W (on ENST00000290567 / NM_001143685.2; = p.R485W on NM_145024.3) | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1257988371, COSV51869757; called by muse, mutect2
- FNIP1 | c.1384A>T p.N462Y | Missense Mutation (SNP) | VAF 104/253 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.051); catalogued as rs760450724; called by muse, mutect2, varscan2
- EVPLL | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 103/269 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PRKCA | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 144/409 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- SIPA1 | c.1973C>T p.T658M | Missense Mutation (SNP) | VAF 267/591 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- HECW2 | c.2916C>T p.D972= | Silent (SNP) | VAF 98/366 reads (27%) | called by muse, mutect2, varscan2
- PCSK6 | c.942G>A p.T314= | Silent (SNP) | VAF 167/364 reads (46%) | catalogued as rs750084393; called by muse, varscan2
